Gene-level copy-number profile of tumor specimen ALCH-B2MP-TTP1-A from ALCHEMIST case ALCH-B2MP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.1 years (23,046 days).
Specimen ALCH-B2MP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b0c7f476-e459-4ec0-8d7e-1988e6d471b3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2MP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/e4ceb37b-fb03-4425-ae1a-af9f470b6908

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 2,688; copy number 2: 54,755; copy number 3: 285; copy number 4: 242; copy number 5: 159; copy number 6: 101; copy number 7: 24; copy number 8: 68; copy number 9: 3; copy number 28: 2.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,038,848–90,053,372, 3 genes: IGKV3D-20, IGKV2D-19, IGKV2D-18.
- chr2:90,114,838–90,115,402, 1 gene (within-gene range 0–1): IGKV3D-15.
- chr2:90,179,889–90,180,587, 1 gene: IGKV2D-10.
- chr2:90,309,230–90,367,699, 4 genes: AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr3:47,413,681–47,513,712, 4 genes: SCAP, AC099778.2, ELP6, BOLA2P2.
- chr3:109,326,141–109,364,234, 2 genes: DPPA4, AC124945.1.
- chr5:69,985,204–69,985,501, 1 gene: CDH12P2.
- chr5:133,052,013–133,106,449, 2 genes: HSPA4, AC113410.3.
- chr7:69,507,510–69,507,622, 1 gene: Y_RNA.
- chr8:69,794,062–70,104,179, 12 genes (within-gene range 0–2): AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2.
- chr10:68,414,064–68,527,523, 6 genes: DNA2, RPL26P29, RNA5SP319, SLC25A16, RPL26P27, Y_RNA.
- chr13:95,310,830–95,394,454, 3 genes: RNY3P8, RNY4P27, MEMO1P5.
- chr15:50,688,900–50,689,193, 1 gene: RN7SL354P.
- chr16:46,656,132–46,931,289, 10 genes: VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2.
- chr16:46,973,989–47,035,385, 3 genes: AC018845.3, AC018845.1, AC018845.2.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr21:12,999,676–13,120,807, 5 genes: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 357 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 9 (within-gene range 2–9): TTC34, AC242022.2, AC242022.1.
- chr5:892,884–956,520, 3 genes, copy number 6: TRIP13, AC122719.3, AC122719.1.
- chr5:10,971,836–11,904,446, 1 gene, copy number 5 (within-gene range 4–5): CTNND2.
- chr5:12,297,399–15,266,541, 30 genes, copy number 5–6: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149.
- chr5:69,560,191–69,920,867, 7 genes, copy number 5–28: GTF2H2C, NAIPP3, AC139495.2, GUSBP3, AC139495.1, GUSBP13, AC131392.1.
- chr5:70,094,659–70,132,973, 2 genes, copy number 6: NAIPP2, CDH12P3.
- chr5:135,802,985–135,803,075, 1 gene, copy number 6: MIR5692C1.
- chr8:90,058,608–92,103,286, 26 genes, copy number 6: CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1.
- chr8:99,013,266–99,877,580, 1 gene, copy number 5 (within-gene range 2–5): VPS13B.
- chr8:99,527,826–100,501,148, 25 genes, copy number 5: Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2.
- chr8:106,980,967–111,236,203, 42 genes, copy number 6: AP003789.1, HMGB1P46, ANGPT1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37.
- chr8:125,648,327–140,458,579, 152 genes, copy number 5–8 (broad region; genes not listed).
- chr8:140,657,900–142,917,843, 56 genes, copy number 5–8 (within-gene range 4–8): PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.1, AC104417.1, AC104417.2, AC103758.1, MIR4472-1, LINC00051, TSNARE1, RN7SL260P, AC134682.1, ADGRB1, MROH4P, ARC, AP006547.1, AC108002.2, JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4, AC083841.3, GML, ZNHIT1P1, CYP11B1, CYP11B2.
- chr8:144,930,358–145,066,685, 8 genes, copy number 5: ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.

Autosomal genes at a single copy (total copy number 1): 2,687. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
